Surgical pathology report (de-identified scan), TCGA case TCGA-GU-A42R, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - UT Southwestern Medical Center at Dallas, specimen TCGA-GU-A42R-01A (Primary Tumor).

[page 1 of 5]
Results**BIOPSY OR SURGICAL SPECIMEN****Patient Information**

Patient Name

MRN

Sex

DOB

Result Information

Status

Edited

Provider Status

Reviewed

Entry Date**Component Results**

Component

Lab

Surgical Pathology

Patient Name:

MR#:

Specimen #:

Procedure/Addenda

Image Analysis Date Ordered:

Status: Signed Out

Date Complete:

Date Reported:

Interpretation

Prognostic markers performed on block A3

BLADDER CANCER RECURRENCE SCORE

p21 by IHC and IMAGE QUANTITATION:

Unaltered

Percent Positive Average: 63%

Staining Intensity Grade: 2

HistoScore: 6

p21 altered range (<10%)

ICD-O-3

Carcinoma, urothelial, NOS

8120/3

Site: bladder, wall, NOS

C67.9

8/27/12
RD

p27 by IHC and IMAGE QUANTITATION:

Altered

Percent Positive Average: 20%

Staining Intensity Grade: 1

HistoScore: 4

p27 altered range (<30%)

p53 by IHC and IMAGE QUANTITATION:

Unaltered

Percent Positive Average: 4 %

Staining Intensity Grade: 2

HistoScore: 4

p53 altered range ($\geq 10\%$)

Ki-67 by IHC and Image QUANTITATION:

Altered

HiPA Discrepancy		

[page 2 of 5]
Percent Positive Average: 23%
Staining Intensity Grade: 2
HistoScore: 5
Ki-67 altered range (>10%)

Cyclin E by IHC and IMAGE QUANTITATION:

Unaltered
Percent Positive Average: 43%
Staining Intensity Grade: 1
HistoScore: 5
Cyclin E altered range (<30%)

INTERPRETATION:

Prognostic Significance: Favorable
2 Biomarker(s) altered
Range: Favorable ≤ 2 altered biomarkers
Unfavorable > 2 altered biomarkers

Comment:

In the above tumor profile the number of altered biomarkers improves the predictive accuracy for patients with PTa-T3 N0 Bladder Cancer. Greater than 2 altered biomarkers are associated with increased risk of recurrence.

data).

Note:

Staining intensity based on 0 (neg) to 3+ (highest)
Percent Positive Average: Percentage of tumor cells staining.
HistoScore = Percentage of tumor cells staining (Scale 0-5) + Intensity (Scale 0-3).
These tests were performed IHC in conjunction with automated image analysis. The performance characteristics of the above tests have been determined in the While some antibodies have not been approved by the FDA, clearance / approval is not mandated. These antibodies are well documented and clinically accepted prognostic indicators.

These tests should not be regarded as part of research investigations. Known positive and negative control tissue show appropriate staining.

The above tumor bio-markers were performed per reflex protocol.

The system used for image quantitation is the .

The method used for antigen retrieval is heat induced epitope retrieval.

College of American Pathologists (CAP) required information for predictive/prognostic markers. Type of specimen fixation and detection system: polymer detection kits are used on formalin-fixed paraffin-embedded sections.

[page 3 of 5]
Clones user: p21 (SX118); p27(SX53G8); p53 (DO-7); Ki-67 (MIB-1); Cyclin E (HE12)

Prognostic markers performed at

Results-Comments
{Not Entered}

Final Diagnosis

Bladder, right wall tumor, transurethral resection (TURBT):

- Invasive papillary urothelial carcinoma, high grade
- Tumor invades muscularis propria
- See CAP template below for further details
- See note

Procedure: TURBT

Histologic Type: Urothelial (transitional cell) carcinoma

Associated Epithelial Lesions: None identified

Histologic Grade (WHO / IUP): High-grade

Tumor Configuration: Papillary

Adequacy of Material for Determining Muscularis Propria Invasion:
Muscularis propria (detrusor muscle) present

Lymph-Vascular Invasion:
Not identified

Microscopic Extent of Tumor:
Tumor invades muscularis propria (detrusor muscle)

The above pathology diagnosis incorporates data elements as outlined in the CAP Cancer Protocols and Checklists which are based on the AJCC/UICC TNM, 7th edition.

Note

Prognostic markers will be ordered on block A3. Results will be reported separately.

This case was reviewed at the

Clinical History

[page 4 of 5]
Bladder cancer
TURBT

Source:
A: Bladder tumor

Gross Description

Received in formalin labeled with the patient's name and "bladder tumor right wall" is a 3.5 x 3 x 2 cm aggregate of soft pink-tan and firm brown tissue fragments. The brown tissue fragments are composed primarily of clotted blood.

Section key:

A1-A9 - entirely submitted (primarily blood clot in cassettes in A5-A9)

Microscopic Description

The stain quality is acceptable.

The microscopic findings are reflected in the diagnosis rendered.

***Electronically Signed Out By

[REDACTED]

Result History

BIOPSY OR SURGICAL SPECIMEN [REDACTED] of [REDACTED] - Order Result History Report.

Result Notes

Notes Recorded by [REDACTED]

Collection Information

Specimen Source
Other

Date and Time
[REDACTED]

Accession #
[REDACTED]

Lab Information

[REDACTED]
[REDACTED]
[REDACTED]

[page 5 of 5]
Status:

This order is currently not shared in

Order

Biopsy or Surgical Specimen

Patient Information

Patient Name

MRN

Sex

DOB

Visit Information

Date

Time

Department

Provider

Visit #

FIN #

Order Information

Order Date and Time

Ordering User

Department

Order

Order Name

Code

Order Number

Biopsy or Surgical Specimen

Order Details

Frequency

Duration

Priority

Order Class

ONE TIME ORDER TASK

1 Occurrence

Routine

Nurse Collect

Order Providers

Authorizing Provider

Encounter Provider

Original Order

Ordered On

Ordered By

Collection Information

Specimen Source

Date and Time

Accession #

Other

Reprint Requisition

Reprint Requisition

BIOPSY OR SURGICAL SPECIMEN

Source: NCI Genomic Data Commons file b739bf4d-363c-4b57-82e9-39e15da59007 (TCGA-GU-A42R.A916842B-DCE7-42FE-82BC-277D09DFC698.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).